CPTAC case C3L-01187 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/634fa99f-3974-4676-91d3-41ddbab15673

Demographics
Sex at birth: female; Race: white; Year of birth: 1998; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 19.4 years (7,079 days); Year of diagnosis: 2017; Days to last known disease status: 1 day; Days to last follow up: 1 day; Calgb risk group: Intermediate/Normal.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1.

Other clinical attributes
- Weight: 87 kg; Height: 156 cm; BMI: 35.75.

Biospecimens (5 samples)
- Samples C3L-01187-50, C3L-01187-52, C3L-01187-53 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-01187-54, C3L-01187-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 1 day; Time between excision and freezing: 180 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
